Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8426, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8426-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGIC DIAGNOSIS:

LEFT KIDNEY, NEPHRECTOMY:

RENAL CELL CARCINOMA, CHROMOPHOBE TYPE, Fuhrman nuclear grade IV of IV (11.5 cm). Extensive tumor necrosis with calcification is present. Frequent mitoses are present.

The carcinoma invades into adipose tissue at the hilum.

The carcinoma invades into the pelvis of the kidney.

The carcinoma is confined by the capsule.

Lymphovascular invasion is present.

The artery, vein, and ureteral margins are free of carcinoma.

The non-neoplastic renal parenchyma will be examined with special stains and the findings reported in an addendum.

CLINICAL DATA:

History: None given.

Operation: Left hand-assisted laparoscopic nephrectomy.

Clinical Diagnosis: Left renal mass.

TISSUE SUBMITTED:

A/1) left kidney (s.s.).

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patients name, unit number, and "#1 - Left kidney", and consists of an 859.8 gram kidney, measuring 19.0 x 12.5 x 7.8 cm, with a ureter (11.0 cm in length x 0.7 cm in diameter), artery (2.0 cm in length x 1.0 cm in diameter), and vein (1.8 cm in length x 1.1 cm in diameter). The specimen is inked black and bi-valved to reveal a multilobulated tan/yellow/pink heterogeneous mass, measuring 11.5 x 10.5 x 5.3 cm, which is located in the lower pole and abuts the kidney capsule. The mass is located 1.3 cm to the vein, 1.4 cm to the artery, and 12.5 cm to the ureter. The mass is predominantly solid with some areas of cystic degeneration and hemorrhage. Some areas of the mass appear golden yellow in color. There is a tan/red/yellow blood clot (? tumor) located in the renal pelvis. Representative sections of the tumor are submitted for cytogenetics and Tissue Bank for special studies. Representative sections of the grossly normal kidney parenchyma are submitted for immunofluorescence, electron microscopy and Tissue Bank for special studies. Gross photographs are taken.

Micro A1: Margins, renal artery, vein, ureter, 3 frags.
Micro A2-A4: representative sections of tumor, 3 frags.
Micro A5-A6: blood clot found in renal pelvis, 2 frags.
Micro A7-A9: tumor in relationship to renal capsule and adipose tissue, 3 frags. RSS.

[page 2 of 2]
Micro A10-A11: tumor in relationship to distal renal vein, 2 frags.
Micro A12: more proximal renal vein, 1 frag.
Micro A13: normal kidney parenchyma, 1 frag.

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

ADDENDUM:

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:

LEFT KIDNEY, NEPHRECTOMY:

- GLOMERULI WITH SIGNS OF HYPERTROPHY AND MILD MESANGIAL EXPANSION, SUGGESTIVE OF AN EARLY DIFFUSE DIABETIC GLOMERULOSCLEROSIS (SEE NOTE)
- MINIMAL CHRONIC CHANGES OF THE KIDNEY PARENCHYMA, MOST LIKELY AGE-RELATED;
- FOCAL GLOBAL GLOMERULOSCLEROSIS (4% OF GLOMERULI);
- TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS (LESS THAN 5% OF THE PARENCHYMA);
- ARTERIAL SCLEROSIS AND ARTERIOLAR HYALINOSIS, MODERATE (SEE NOTE)

NOTE:

The glomeruli reveal mild signs of hypertrophy of the tuft and mild expansion of the mesangial matrix; although these changes are rather non-specific, they suggest an incipient or early diffuse diabetic glomerulosclerosis, since the patient's chart reveal abnormal levels of serum glucose. The overall kidney parenchyma sample examined shows minor chronic changes, within the expected range for a 50-year-old man. There is minimal focal global glomerulosclerosis (4% of glomeruli), and minimal tubular atrophy and interstitial fibrosis (less than 5% of the parenchyma). However, the arterial and arteriolar vessels reveal a moderate degree of vascular sclerosis or scarring.

The kidney parenchyma has been reviewed by
Renal Pathologists.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin embedded tissue (block A13) were evaluated using HE, PAS, Jones silver methenamine, and AFOG (trichrome) stains.

The sample consists of cortex and medulla. There are 151 glomeruli present, of which 6 (4%) are globally sclerosed. The remaining glomeruli show mild signs of hypertrophy with also mild expansion of the mesangial areas by matrix elements. There are no discernible craters or double contours of the glomerular capillary wall basement membranes on PAS and Jones' silver stain. Rare distal tubules contain PAS-positive hyaline casts. There is focal interstitial inflammation by mononuclear cells, mostly in areas of tubular atrophy. Focal extravasation of Tamm-Horsfall protein is also recognized. Less than 5% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis as seen on trichrome stain (AFOG). Arteries and arterioles exhibit moderate degree of sclerosis of the wall with focal substitution of

Source: NCI Genomic Data Commons file 268e1cc3-db8d-4bfb-8cfc-890b7491c4fe (TCGA-KN-8426.0467A5C3-3959-45BB-8D3A-D4FC8E7D2EBC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).